Somatic mutation profile of tumor specimen 3ca0ab23-70ae-4083-bd7d-9f71d8 (aliquot 3ca0ab23-70ae-4083-bd7d-9f71d8_D6_2) from CPTAC case 11CO047, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 3ca0ab23-70ae-4083-bd7d-9f71d8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fef7b9c7-9136-4383-97cf-673c1422b253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 9eb5c82b-8609-47ac-bf8b-87782a (Blood Derived Normal), aliquot 9eb5c82b-8609-47ac-bf8b-87782a_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9de64a1-e71b-4439-9e26-4585cad17b3e

The open-access MAF lists 151 somatic variants for this specimen: 105 protein-altering or splice-affecting, 34 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 34, Intron 7, Nonsense Mutation 5, Frame Shift Ins 5, Frame Shift Del 4, 3'UTR 3, Splice Site 2, Splice Region 2, Nonstop Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG11 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907183, CM122079; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 67/133 reads (50%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- MAPKBP1 | c.4393C>T p.R1465* (on ENST00000456763 / NM_001128608.2; = p.R1459* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | catalogued as rs1057519304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 61/366 reads (17%) | catalogued as rs1560311554, COSV53199004; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.898T>A p.Y300N | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV55947967; called by muse, mutect2, varscan2
- ACADL | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs774761910, COSV52054469; called by muse, mutect2, varscan2
- ACSM2B | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV61657732; called by muse, mutect2, varscan2
- AIFM1 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 161/251 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54854850; called by muse, mutect2, varscan2
- ANKRD35 | c.1787T>C p.L596P | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1553739184; called by muse, mutect2, varscan2
- APC | c.4314del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 71/165 reads (43%) | catalogued as COSV57354045, COSV57378825; called by mutect2, pindel, varscan2
- APC2 | c.3338C>T p.T1113M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs753641138, COSV99279335; called by muse, mutect2, varscan2
- BCL11A | c.832G>A p.A278T (on ENST00000335712 / NM_001365609.1; = p.A312T on NM_018014.4) | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.29); catalogued as COSV100184971; called by muse, mutect2, varscan2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2, varscan2
- CARD6 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs566975527, COSV54565417; called by muse, mutect2, varscan2
- CC2D2B | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs746059331; called by muse, mutect2, varscan2
- CCDC144A | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs528151648; called by muse, mutect2, varscan2
- CCT8L2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs147789853, CM142324; called by muse, mutect2, varscan2
- CHCHD2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs200784526, COSV68170030; called by muse, mutect2, varscan2
- CNR1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs772492894, COSV62989613; called by muse, mutect2, varscan2
- DENND2C | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV67923973; called by muse, mutect2, varscan2
- DGKZ | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1439192939; called by muse, mutect2, varscan2
- DLG5 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763293996; called by muse, mutect2, varscan2
- ENAM | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68536137; called by muse, mutect2, varscan2
- FBXW7 | c.1318G>A p.D440N (on ENST00000281708 / NM_001349798.2; = p.D360N on NM_018315.5) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55895832, COSV99662862; called by muse, mutect2, varscan2
- FNDC1 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs377571503; called by muse, varscan2
- GARS1 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs753078831; called by muse, mutect2, varscan2
- GSTM2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140199111, COSV53981770; called by muse, mutect2, varscan2
- HMCN1 | c.13288C>T p.R4430C | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141440732; called by muse, mutect2, varscan2
- IGF2BP1 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751477755; called by muse, mutect2, varscan2
- KCNA3 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs763882202; called by muse, mutect2
- KIF22 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | catalogued as rs780144771, COSV50716610; called by muse, mutect2
- KRT34 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as rs779910638, COSV101222727; called by muse, mutect2, varscan2
- KRTAP2-3 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as rs1003863763; called by muse, mutect2, varscan2
- LPAR1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs755789465, COSV62689039; called by muse, mutect2, varscan2
- LRP6 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53796545; called by muse, mutect2, varscan2
- NCCRP1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769710252, COSV100355820, COSV59212384; called by muse, mutect2, varscan2
- NKAPL | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775747890, COSV59197418; called by muse, mutect2, varscan2
- NYAP2 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311059994, COSV56017053; called by muse, mutect2, varscan2
- PBX1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1433807647; called by muse, mutect2
- PCBP4 | c.712G>A p.G238S (on ENST00000322099 / NM_033010.2; = p.G195S on NM_020418.4) | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778605841, COSV104398147; called by muse, mutect2, varscan2
- PCDHGA9 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 113/205 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.075); catalogued as COSV53908599; called by muse, mutect2, varscan2
- PHRF1 | c.2980C>T p.R994C (on ENST00000264555 / NM_001286581.2; = p.R993C on NM_020901.4) | Missense Mutation (SNP) | VAF 126/447 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs760052093; called by muse, mutect2, varscan2
- PITRM1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs906337951, COSV56535161; called by muse, mutect2, varscan2
- PLXNA1 | c.2618C>T p.T873M | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as rs549841697, COSV99302406; called by muse, varscan2
- PZP | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1352555418; called by muse, mutect2, varscan2
- SLC4A5 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs745602085; called by muse, mutect2, varscan2
- SLC6A4 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268954204, COSV99911579; called by muse, mutect2, varscan2
- SLF1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1470713752; called by muse, mutect2, varscan2
- SLK | c.2830C>T p.L944F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.852); catalogued as rs1246408561; called by muse, mutect2, varscan2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, varscan2
- TDRD9 | c.3451G>A p.G1151R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752004479; called by muse, mutect2, varscan2
- TMEM273 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs372203141; called by muse, mutect2, varscan2
- TRAPPC2 | c.59T>A p.M20K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV62897102; called by muse, mutect2, varscan2
- TRPV4 | c.1892-7C>T | Splice Region (SNP) | VAF 59/310 reads (19%) | catalogued as rs1346854160; called by muse, mutect2, varscan2
- TSHZ3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368424576; called by muse, mutect2, varscan2
- TTLL5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs534989089, COSV100089825; called by muse, mutect2, varscan2
- WDR64 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63796893; called by muse, mutect2, varscan2
- XCR1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183698296, COSV58569784; called by muse, mutect2, varscan2
- ZNF843 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV59848115; called by muse, mutect2, varscan2
- ABCA6 | c.3378dup p.S1127Qfs*25 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.5480G>T p.G1827V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ANKS4B | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1394T>C p.I465T | Missense Mutation (SNP) | VAF 76/506 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD11 | c.1613C>A p.P538H (on ENST00000280758 / NM_001018072.2; = p.P75H on NM_001017523.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTBD8 | c.1880G>T p.G627V (on ENST00000636805 / NM_001376131.1; = p.G114V on NM_015237.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C11orf49 | c.535_556dup p.P186Qfs*33 | Frame Shift Ins (INS) | VAF 30/124 reads (24%) | called by mutect2, varscan2
- CADM2 | c.382C>A p.Q128K (on ENST00000407528 / NM_001167674.2; = p.Q130K on NM_153184.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CFAP299 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CFAP54 | c.7766A>G p.D2589G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CSMD3 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.248); called by muse, mutect2
- DDX1 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX40 | c.727A>C p.N243H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by mutect2, varscan2
- DOCK10 | c.5756A>G p.D1919G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FAT1 | c.9327del p.S3110Vfs*6 | Frame Shift Del (DEL) | VAF 38/287 reads (13%) | called by mutect2, pindel, varscan2
- FOCAD | c.1894G>T p.G632C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJC3 | c.138T>A p.D46E | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- HIVEP3 | c.6253C>T p.P2085S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL11 | c.86dup p.R30Sfs*38 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by pindel, varscan2
- INTS6 | c.1181-1G>C p.X394_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- KIAA1549L | c.3188-1G>C p.X1063_splice (on ENST00000321505; = p.X1360_splice on NM_012194.3) | Splice Site (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- MED8 | c.806G>C p.*269Sext*31 | Nonstop Mutation (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- MYCBP2 | c.1011dup p.L338Sfs*11 (on ENST00000357337; = p.L376Sfs*11 on NM_015057.5) | Frame Shift Ins (INS) | VAF 23/242 reads (10%) | called by mutect2, pindel, varscan2
- NBN | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NCAM2 | c.682A>C p.M228L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- NOL4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOS1 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NRK | c.3508G>C p.G1170R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDH10 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 158/469 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PKHD1L1 | c.4721C>T p.S1574F | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PON3 | c.579dup p.E194* | Frame Shift Ins (INS) | VAF 96/370 reads (26%) | called by mutect2, pindel, varscan2
- R3HCC1L | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RGPD4 | c.2947G>T p.G983* | Nonsense Mutation (SNP) | VAF 62/322 reads (19%) | called by mutect2, varscan2
- RRP36 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SPAG7 | c.417+3G>A | Splice Region (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- SPDYE2 | c.303del p.L102Sfs*3 | Frame Shift Del (DEL) | VAF 74/671 reads (11%) | called by mutect2, pindel, varscan2
- TAF2 | c.2365T>G p.F789V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- TDRD7 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TOP1 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- TTLL2 | c.1754_1772del p.K585Ifs*5 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- TTN | c.61482A>T p.K20494N (on ENST00000591111; = p.K13070N on NM_003319.4) | Missense Mutation (SNP) | VAF 30/153 reads (20%) | PolyPhen possibly damaging (0.747); called by muse, mutect2
- TWSG1 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VWF | c.2999A>T p.D1000V | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YEATS2 | c.2766G>A p.M922I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF266 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ZNF618 | c.1661A>G p.H554R (on ENST00000374126 / NM_001318042.2; = p.H461R on NM_133374.2) | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABHD2 | c.244T>C p.L82= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- ACSM4 | c.738C>T p.L246= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs372292869; called by muse, mutect2, varscan2
- ADAMTS7 | c.2463C>T p.P821= | Silent (SNP) | VAF 77/226 reads (34%) | catalogued as rs149239067; called by muse, mutect2, varscan2
- ANKEF1 | c.663T>C p.A221= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- ARHGAP45 | c.147G>A p.P49= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as rs750801168, COSV54028260; called by muse, mutect2, varscan2
- CACNA1G | c.3678C>T p.D1226= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs752544601; called by muse, mutect2, varscan2
- CALD1 | c.1629C>T p.R543= (on ENST00000361675 / NM_033138.4; = p.R288= on NM_004342.7) | Silent (SNP) | VAF 33/303 reads (11%) | catalogued as rs779036893, COSV62652806; called by muse, mutect2, varscan2
- CCDC102A | c.1476G>A p.T492= | Silent (SNP) | VAF 34/245 reads (14%) | catalogued as rs757108364; called by muse, mutect2, varscan2
- CCDC87 | c.2085C>T p.D695= | Silent (SNP) | VAF 110/365 reads (30%) | called by muse, mutect2, varscan2
- CLEC6A | c.57A>G p.R19= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CLIP2 | c.315G>A p.P105= | Silent (SNP) | VAF 91/324 reads (28%) | called by muse, mutect2, varscan2
- CLPB | c.1470C>T p.I490= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- CSMD3 | c.1158C>T p.T386= | Silent (SNP) | VAF 36/358 reads (10%) | catalogued as COSV52123858; called by muse, mutect2
- DLEU7 | c.642C>A p.I214= | Silent (SNP) | VAF 41/298 reads (14%) | called by muse, mutect2, varscan2
- FAT4 | c.4848A>G p.E1616= | Silent (SNP) | VAF 50/349 reads (14%) | called by muse, mutect2, varscan2
- FCRL4 | c.1167C>T p.A389= | Silent (SNP) | VAF 36/193 reads (19%) | catalogued as rs761950047, COSV54863994, COSV54866565; called by muse, mutect2, varscan2
- FOXE1 | c.867G>A p.P289= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs940947787; called by muse, mutect2
- GPR55 | c.273G>A p.P91= | Silent (SNP) | VAF 64/359 reads (18%) | catalogued as rs370767476; called by muse, mutect2, varscan2
- HAS1 | c.594G>A p.A198= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as rs779923824; called by muse, mutect2, varscan2
- HELZ2 | c.2496C>T p.V832= (on ENST00000467148 / NM_001037335.2; = p.V263= on NM_033405.3) | Silent (SNP) | VAF 22/279 reads (8%) | catalogued as rs1195463213; called by muse, mutect2
- KIAA1109 | c.4497G>T p.V1499= | Silent (SNP) | VAF 45/286 reads (16%) | catalogued as rs1262263567; called by muse, mutect2, varscan2
- LILRB1 | c.426C>A p.G142= (on ENST00000427581; = p.G106= on NM_006669.6) | Silent (SNP) | VAF 46/420 reads (11%) | called by muse, mutect2, varscan2
- MEGF8 | c.3261G>A p.P1087= (on ENST00000251268 / NM_001271938.2; = p.P1020= on NM_001410.3) | Silent (SNP) | VAF 49/303 reads (16%) | catalogued as rs377425535, COSV52096436; called by muse, mutect2, varscan2
- MUC16 | c.12750G>T p.T4250= | Silent (SNP) | VAF 112/293 reads (38%) | catalogued as COSV67470997; called by muse, mutect2, varscan2
- PCDH11X | c.114C>T p.V38= | Silent (SNP) | VAF 86/521 reads (17%) | catalogued as rs1157037577, COSV53452941; called by muse, mutect2, varscan2
- PIEZO2 | c.3801G>A p.A1267= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs776448840; called by muse, mutect2, varscan2
- RABIF | c.183C>T p.D61= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as rs750544846, COSV66131522; called by muse, mutect2, varscan2
- SLITRK5 | c.1194C>A p.I398= | Silent (SNP) | VAF 190/522 reads (36%) | catalogued as COSV100280342, COSV61521915; called by muse, mutect2, varscan2
- SLITRK6 | c.1047G>A p.E349= | Silent (SNP) | VAF 80/374 reads (21%) | catalogued as rs758898828; called by muse, mutect2, varscan2
- SYT10 | c.1113T>A p.L371= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- TONSL | c.2169G>A p.A723= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs200147646, COSV101340225; called by muse, varscan2
- XKR7 | c.1467G>A p.A489= | Silent (SNP) | VAF 60/587 reads (10%) | catalogued as rs768945855, COSV101629222; called by muse, mutect2, varscan2
- ZNF831 | c.222C>T p.R74= | Silent (SNP) | VAF 137/305 reads (45%) | catalogued as rs763329350, COSV64040907, COSV64042592; called by muse, mutect2, varscan2
- ZNF831 | c.1032G>T p.S344= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as COSV64045926; called by muse, mutect2
- ARPP21 | c.1644+899A>T | Intron (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- CLEC18B | c.*18C>G | 3'UTR (SNP) | VAF 40/233 reads (17%) | called by mutect2, varscan2
- FGF12 | c.414+66628C>T | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as rs1231670110, COSV53161876; called by muse, mutect2, varscan2
- FOXP2 | c.*3353G>A | 3'UTR (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- LMF1 | chr16:975919 C>G | 5'Flank (SNP) | VAF 72/358 reads (20%) | called by muse, mutect2, varscan2
- PLPP5 | c.635-368A>C | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- PNMA6A | chrX:153076543 C>T | 3'Flank (SNP) | VAF 135/815 reads (17%) | catalogued as rs1218829419; called by muse, mutect2, varscan2
- RAB18 | c.68+664C>A | Intron (SNP) | VAF 25/174 reads (14%) | called by mutect2, varscan2
- RALGPS1 | c.1248-1368G>A | Intron (SNP) | VAF 22/119 reads (18%) | catalogued as rs922732793; called by muse, mutect2, varscan2
- SND1 | c.2110+387G>A | Intron (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- ZMPSTE24 | c.*46dup | 3'UTR (INS) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ZNF268 | c.33+2677C>T | Intron (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
